Somatic mutation profile of tumor specimen MP2PRT-PAPGKN-TMP1-A (aliquot MP2PRT-PAPGKN-TMP1-A-1-0-D-A834-36) from MP2PRT case MP2PRT-PAPGKN, project MP2PRT-ALL (Molecular Profiling to Predict Response to Treatment for Acute Lymphoblastic Leukemia). Sex at birth: female; Primary diagnosis: Acute lymphoblastic leukemia, NOS; Tissue or organ of origin: Bone marrow; Age at diagnosis: 3.9 years (1,422 days).
Specimen MP2PRT-PAPGKN-TMP1-A: Sample type: Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Whole Bone Marrow; Biospecimen anatomic site: Bone Marrow; Preservation method: Cryopreserved.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 61cc29ac-6378-4f25-a24a-37b1984ef6ec.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MP2PRT-PAPGKN-NM1-A (Blood Derived Cancer - Bone Marrow, Post-treatment; tissue type Normal — post-treatment blood used as the germline comparator), aliquot MP2PRT-PAPGKN-NM1-A-1-0-D-A834-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/96b17327-b6f5-434c-89e7-043976de92dd

The open-access MAF lists 12 somatic variants for this specimen: 9 protein-altering or splice-affecting, 1 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 7, 5'Flank 1, Nonsense Mutation 1, Silent 1, RNA 1, Frame Shift Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- NRAS | c.34G>A p.G12S | Missense Mutation (SNP) | VAF 197/434 reads (45%) | hotspot (GDC flag); SIFT deleterious (0.03); PolyPhen benign (0.369); catalogued as rs121913250, CM136798, COSV54736487, COSV54736621, COSV54736940; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- DSCAM | c.1952C>T p.T651M | Missense Mutation (SNP) | VAF 193/774 reads (25%) | SIFT tolerated (0.25); PolyPhen probably damaging (0.999); catalogued as rs778265366, COSV68021082; called by muse, mutect2, varscan2
- FRMPD3 | c.5123G>A p.R1708Q | Missense Mutation (SNP) | VAF 227/732 reads (31%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.952); catalogued as rs747726417; called by muse, mutect2, varscan2
- PAPLN | c.714G>A p.W238* (on ENST00000554301; = p.W211* on NM_173462.4) | Nonsense Mutation (SNP) | VAF 172/579 reads (30%) | catalogued as rs1330734427; called by muse, varscan2
- PRDM15 | c.3193G>A p.G1065S | Missense Mutation (SNP) | VAF 143/663 reads (22%) | SIFT tolerated, low confidence (0.06); PolyPhen probably damaging (0.939); catalogued as rs761322637; called by muse, mutect2, varscan2
- FGF13 | c.68del p.P23Lfs*19 | Frame Shift Del (DEL) | VAF 106/376 reads (28%) | called by mutect2, pindel, varscan2
- HSPA1B | c.1660G>A p.E554K | Missense Mutation (SNP) | VAF 218/809 reads (27%) | SIFT tolerated, low confidence (0.14); PolyPhen benign (0.093); called by muse, mutect2, varscan2
- PLXDC2 | c.269G>T p.R90I | Missense Mutation (SNP) | VAF 141/592 reads (24%) | SIFT tolerated (0.18); PolyPhen benign (0.091); called by muse, mutect2, varscan2
- RAB42 | c.226G>A p.E76K | Missense Mutation (SNP) | VAF 223/465 reads (48%) | SIFT tolerated (0.17); PolyPhen benign (0.027); called by muse, mutect2, varscan2
- PCDH19 | c.2976G>A p.A992= (on ENST00000373034 / NM_001184880.2; = p.A944= on NM_020766.3) | Silent (SNP) | VAF 249/838 reads (30%) | catalogued as rs772345040; called by muse, mutect2, varscan2
- NXF5 | n.433G>A | RNA (SNP) | VAF 88/356 reads (25%) | called by muse, mutect2, varscan2
- REXO1L1P | chr8:85663096 G>A | 5'Flank (SNP) | VAF 43/449 reads (10%) | catalogued as rs1186544323; called by muse, mutect2, varscan2
